Somatic mutation profile of tumor specimen HCM-CSHL-0179-C25-01A (aliquot HCM-CSHL-0179-C25-01A-11D-A78T-36) from HCMI case HCM-CSHL-0179-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.3 years (22,008 days).
Specimen HCM-CSHL-0179-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eb80809-f489-4dd1-96c6-0c2754746d25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0179-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0179-C25-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9acd5424-955e-4fed-893b-2b45c37492b0

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, RNA 3, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.6442G>A p.D2148N | Missense Mutation (SNP) | VAF 152/428 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs111033271, CM021546; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/236 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TAT | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 146/520 reads (28%) | catalogued as rs118203914, CM920661, COSV63532532; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 187/474 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs200778107; called by muse, mutect2, varscan2
- ADGRB3 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs113677156, COSV65405340; called by muse, mutect2, varscan2
- ALPP | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs759881416; called by muse, mutect2, varscan2
- CD276 | c.1120C>T p.R374W (on ENST00000318443 / NM_001024736.2; = p.R156W on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754785892, COSV100573437; called by muse, mutect2, varscan2
- CNTN5 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201144555, COSV54301785; called by muse, mutect2, varscan2
- COL11A1 | c.4131A>T p.K1377N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV62192406; called by muse, mutect2, varscan2
- CTNND2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773745550, COSV58868584; called by muse, mutect2, varscan2
- CUL9 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146080256; called by muse, mutect2, varscan2
- FAM241B | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 78/503 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as rs1016187687; called by muse, mutect2, varscan2
- GLI2 | c.2000C>T p.P667L (on ENST00000361492 / NM_001374353.1; = p.P684L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs373968370; called by muse, mutect2, varscan2
- IRX2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV57412579; called by muse, mutect2, varscan2
- LRFN1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1282656157, COSV99953486; called by muse, mutect2, varscan2
- MAP3K21 | c.1957G>T p.G653* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV64041102; called by muse, mutect2
- MDM2 | c.961dup p.L321Pfs*13 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | catalogued as rs746910913; called by mutect2, varscan2
- MYO18A | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566347249; called by mutect2, varscan2
- OR51B6 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs112049705, COSV66512594; called by muse, mutect2, varscan2
- PODN | c.1919G>A p.R640H (on ENST00000395871; = p.R592H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs750891509, COSV57014653; called by muse, varscan2
- PTPRO | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 105/357 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55523950; called by muse, mutect2, varscan2
- RFPL1 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs542404003; called by muse, mutect2, varscan2
- SEC13 | c.647G>A p.R216Q (on ENST00000350697 / NM_183352.3; = p.R219Q on NM_030673.4) | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs754016117, COSV99046690; called by muse, mutect2, varscan2
- SEZ6L | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.427); catalogued as rs760398959, COSV50690159; called by muse, mutect2, varscan2
- SHCBP1L | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 74/539 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs754623560; called by muse, varscan2
- SIGLEC7 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771229132, COSV99978326; called by muse, mutect2
- SLC22A10 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs200183991; called by muse, mutect2, varscan2
- SPEG | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs775824354, COSV56673806; called by muse, mutect2, varscan2
- TARM1 | c.260C>T p.A87V (on ENST00000616041 / NM_001330650.1; = p.A79V on NM_001135686.3) | Missense Mutation (SNP) | VAF 65/858 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs758163798, COSV101444635, COSV71524932; called by muse, mutect2
- TENM3 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.258); catalogued as rs759712953, COSV69315835; called by muse, mutect2, varscan2
- TSPAN5 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762215531, COSV59879415; called by muse, mutect2, varscan2
- UMOD | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 90/529 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs778464982; called by muse, mutect2, varscan2
- VWA5B1 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs562282893, COSV57061584; called by muse, mutect2, varscan2
- ACVR1B | c.634_635del p.I212Yfs*18 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- ADCY2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKN2A | c.291_292del p.H98Pfs*21 | Frame Shift Del (DEL) | VAF 196/603 reads (33%) | called by mutect2, pindel, varscan2
- LRBA | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- MAST2 | c.4892C>G p.S1631C | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1L | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NPIPB2 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 144/571 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PPP1R21 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SMIM21 | c.261-2A>T p.X87_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 26/258 reads (10%) | called by mutect2, pindel, varscan2
- WDR97 | c.2307G>A p.K769= | Splice Region (SNP) | VAF 61/322 reads (19%) | called by muse, mutect2, varscan2
- XPO5 | c.383G>A p.W128* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- ADAD1 | c.162G>A p.T54= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs139626702; called by muse, varscan2
- AHNAK | c.14997T>G p.T4999= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- ALPP | c.1380G>A p.A460= | Silent (SNP) | VAF 184/696 reads (26%) | catalogued as rs1261155097; called by muse, mutect2, varscan2
- IPO4 | c.2502C>T p.H834= | Silent (SNP) | VAF 30/270 reads (11%) | catalogued as rs767137886, COSV61016614; called by muse, mutect2, varscan2
- KIDINS220 | c.1239C>T p.S413= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- LAMC3 | c.546C>T p.G182= | Silent (SNP) | VAF 187/429 reads (44%) | catalogued as rs771073233, COSV63094599; called by muse, mutect2, varscan2
- MDN1 | c.6201A>T p.P2067= | Silent (SNP) | VAF 95/446 reads (21%) | called by muse, mutect2, varscan2
- MYO15A | c.1671C>T p.F557= | Silent (SNP) | VAF 43/290 reads (15%) | catalogued as rs879619613, COSV99234779; called by muse, mutect2, varscan2
- SLC13A4 | c.1515C>T p.T505= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs772841017, COSV100818826; called by muse, mutect2, varscan2
- TNRC6B | c.1092G>A p.Q364= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- FAM90A20P | n.1203C>T | RNA (SNP) | VAF 67/595 reads (11%) | catalogued as rs1443663189; called by muse, mutect2, varscan2
- GBA3 | c.59-8111T>A | Intron (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- MIR99AHG | n.622A>T | RNA (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- OSBPL8 | c.218-11943G>A | Intron (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- RPS26P15 | n.275G>A | RNA (SNP) | VAF 44/269 reads (16%) | catalogued as rs768731084; called by muse, mutect2, varscan2
